Somatic mutation profile of tumor specimen TCGA-V4-A9F8-01A (aliquot TCGA-V4-A9F8-01A-11D-A39W-08) from TCGA case TCGA-V4-A9F8, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mixed epithelioid and spindle cell melanoma; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 68.9 years (25,168 days).
Specimen TCGA-V4-A9F8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 57c2eadc-75fd-4624-9816-5b9b4cfa8b0c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V4-A9F8-10A (Blood Derived Normal), aliquot TCGA-V4-A9F8-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f4619f18-9eea-436a-be36-889c8f1b6283

The open-access MAF lists 22 somatic variants for this specimen: 17 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 12, Silent 5, Frame Shift Ins 2, Nonsense Mutation 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAQ | c.626A>C p.Q209P | Missense Mutation (SNP) | VAF 38/82 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121913492, COSV54105903, COSV54105914, COSV54108414; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- B4GALT4 | c.334C>T p.R112W | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs781226310; called by muse, mutect2, varscan2
- BAP1 | c.203A>G p.D68G | Missense Mutation (SNP) | VAF 11/12 reads (92%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as rs1194652468, COSV56240608; called by muse, mutect2, varscan2
- NCKAP5L | c.1690C>T p.R564W | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as rs764426987; called by muse, mutect2, varscan2
- SLC30A1 | c.979A>G p.I327V | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs771486914; called by muse, mutect2, varscan2
- SPEG | c.5303T>C p.I1768T | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1382597576; called by muse, mutect2, varscan2
- XKR4 | c.421C>T p.Q141* | Nonsense Mutation (SNP) | VAF 13/112 reads (12%) | catalogued as COSV59325910; called by muse, mutect2, varscan2
- ANKRD6 | c.772_780del p.L258_T260del | In Frame Del (DEL) | VAF 39/105 reads (37%) | called by mutect2, pindel, varscan2
- CCDC89 | c.40A>C p.M14L | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- GPC5 | c.1685dup p.S563Kfs*22 | Frame Shift Ins (INS) | VAF 70/150 reads (47%) | called by mutect2, pindel, varscan2
- ING3 | c.771_774dup p.D259* | Frame Shift Ins (INS) | VAF 16/53 reads (30%) | called by mutect2, pindel, varscan2
- MED12 | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 12/12 reads (100%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- MROH1 | c.475G>A p.V159I | Missense Mutation (SNP) | VAF 69/135 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- N4BP2 | c.4985A>C p.H1662P | Missense Mutation (SNP) | VAF 61/117 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NDUFAF6 | c.868C>T p.Q290* | Nonsense Mutation (SNP) | VAF 54/125 reads (43%) | called by muse, mutect2, varscan2
- SMCR8 | c.2146C>A p.Q716K | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TRPV2 | c.7T>G p.S3A | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.058); called by muse, mutect2
- ADAMTS12 | c.3933C>T p.G1311= | Silent (SNP) | VAF 14/120 reads (12%) | catalogued as COSV100711108; called by muse, mutect2, varscan2
- DYNC1I2 | c.1645T>C p.L549= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs1489997404; called by muse, mutect2, varscan2
- IQGAP2 | c.3108A>G p.T1036= | Silent (SNP) | VAF 10/88 reads (11%) | called by muse, mutect2, varscan2
- RYR1 | c.2550C>T p.F850= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as rs757850226, COSV100615193, COSV62101418; called by muse, mutect2, varscan2
- VPS35L | c.960A>C p.T320= | Silent (SNP) | VAF 14/25 reads (56%) | called by muse, mutect2, varscan2
